Gene-level copy-number profile of tumor specimen SM-JU354 from CPTAC case C289419, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU354: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d45ea48a-644d-44fe-a59e-45d4c288e60f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105213 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/ee1784c1-67cf-433f-9101-841fd5aed076

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 122; copy number 1: 11,936; copy number 2: 38,797; copy number 3: 7,852; copy number 4: 176; copy number 5: 26; copy number 6: 9.

Homozygous deletions (total copy number 0; autosomes only): 122 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,915,871–7,943,165, 2 genes: TNFRSF9, AL009183.1.
- chr1:16,440,721–16,552,531, 10 genes: NECAP2, LINC01772, CROCCP3, RNU1-1, AL137802.2, AL137802.3, AL137802.1, LINC01783, RNU1-6P, AL355149.1.
- chr4:147,916,529–147,917,386, 1 gene (within-gene range 0–1): AC115621.1.
- chr4:148,445,703–149,024,624, 3 genes (within-gene range 0–1): AC002460.2, ASS1P8, RNA5SP166.
- chr4:148,819,351–149,154,175, 5 genes: AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430.
- chr4:149,789,952–149,790,303, 1 gene (within-gene range 0–1): AKIRIN2P1.
- chr9:21,524,307–23,682,662, 28 genes (within-gene range 0–1): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:23,894,990–23,898,054, 1 gene: AL365204.2.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr14:18,667,249–19,957,996, 66 genes (broad region; genes not listed).
- chr14:23,938,219–24,052,555, 4 genes (within-gene range 0–1): DHRS4-AS1, DHRS4, DHRS4L2, AL136419.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,878,835–9,729,114, 26 genes, copy number 5 (within-gene range 2–5): ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201, PIK3CD, PIK3CD-AS1, AL691449.1, PIK3CD-AS2.
- chr4:52,252,820–52,551,574, 3 genes, copy number 6: AC097522.2, AC097522.1, RNU6-1252P.
- chr4:54,657,918–54,740,715, 1 gene, copy number 6: KIT.
- chr7:54,752,250–55,211,628, 5 genes, copy number 6: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1.

Autosomal genes at a single copy (total copy number 1): 9,080. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
